Somatic mutation profile of tumor specimen ASCProject_0097_T4_WES (aliquot ASCProject_0097_T4_WES_1) from CMI case ASCProject_0097, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 38.5 years (14,044 days).
Specimen ASCProject_0097_T4_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Chin; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b83f4c1-8f7c-4604-8b59-e2b948d6610a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0097_SALIVA_2 (Saliva), aliquot ASCProject_0097_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f3bf653-c2e8-4b97-978e-8f8a0ccc4bf0

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Splice Site 5, Frame Shift Del 3, Intron 3, 3'UTR 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG10B | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV58142625; called by muse, mutect2
- ARID1B | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs558155146, COSV51649102; called by muse, mutect2, varscan2
- CENPJ | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs142121392; called by muse, mutect2, varscan2
- CSMD2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1436948628, COSV99586366; called by muse, mutect2, varscan2
- CSMD2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1330969566, COSV99586370; called by muse, mutect2, varscan2
- DDRGK1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs779149576; called by muse, mutect2, varscan2
- DNM3 | c.1675T>C p.Y559H (on ENST00000355305 / NM_001350206.2; = p.Y549H on NM_015569.5) | Missense Mutation (SNP) | VAF 23/391 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1407070265; called by muse, mutect2
- DOCK5 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs376187554; called by muse, mutect2, varscan2
- DUXA | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as rs371962814; called by muse, mutect2, varscan2
- ELMO2 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as rs760009580, COSV51682755, COSV51686266; called by muse, mutect2, varscan2
- EML3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs1165597557, COSV53874634; called by muse, mutect2, varscan2
- GRID1 | c.1275G>T p.L425F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs760589522; called by muse, mutect2, varscan2
- GYS1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as rs1203781149; called by muse, mutect2, varscan2
- KCNH5 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1313204598, COSV59753452; called by muse, mutect2, varscan2
- LMAN2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs747269398, COSV57426136; called by muse, mutect2, varscan2
- LRRC71 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100503950; called by muse, mutect2, varscan2
- MAN2A1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs375505532; called by muse, mutect2, varscan2
- MATN3 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 79/108 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV68099761; called by muse, mutect2, varscan2
- MUC4 | c.15694G>T p.V5232F (on ENST00000463781 / NM_018406.7; = p.V996F on NM_004532.6) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as rs755720714; called by muse, mutect2, varscan2
- NRCAM | c.2432C>T p.T811M (on ENST00000379028 / NM_001371124.1; = p.T795M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766439513, COSV100694300; called by muse, mutect2, varscan2
- PARP8 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.549); catalogued as rs775424928; called by muse, mutect2, varscan2
- PLCB4 | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 34/234 reads (15%) | catalogued as COSV53793125; called by muse, mutect2, varscan2
- SYPL1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as rs1287770543, COSV99163439; called by muse, mutect2, varscan2
- USH1G | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746860881; called by muse, mutect2, varscan2
- ZIC5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1405550387; called by muse, mutect2, varscan2
- ZNF614 | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54545807; called by muse, mutect2, varscan2
- ZRANB2 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 126/436 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs751149078; called by muse, varscan2
- ABCC4 | c.3748G>A p.G1250R | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BABAM1 | c.786+1G>A p.X262_splice | Splice Site (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2
- CAMP | c.389A>T p.K130M (on ENST00000296435; = p.K127M on NM_004345.5) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP78 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COQ6 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.248); called by mutect2, varscan2
- DDX23 | c.2064+1G>C p.X688_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- DENR | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- FOLH1B | n.1946-1G>T | Splice Site (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FOXI1 | c.487_488del p.S163Qfs*41 | Frame Shift Del (DEL) | VAF 78/230 reads (34%) | called by pindel, varscan2
- GREB1L | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK2 | c.2394G>T p.W798C | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM4 | c.1689C>A p.D563E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HEG1 | c.3444G>C p.Q1148H | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- HLA-G | c.295A>G p.R99G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNRNPA0 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HSPB8 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF4B | c.646T>A p.F216I | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEPE | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYO1F | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHSL1 | c.676+5_676+8del | Splice Region (DEL) | VAF 31/59 reads (53%) | called by mutect2, pindel, varscan2
- NLRP3 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- OR52I2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- PLXNA1 | c.3276+1G>T p.X1092_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- POU5F2 | c.904_905del p.I302Pfs*55 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- SALL1 | c.3709T>C p.Y1237H | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SEMA4A | c.56del p.F19Sfs*51 | Frame Shift Del (DEL) | VAF 93/447 reads (21%) | called by mutect2, pindel, varscan2
- SH2D3C | c.1768C>G p.L590V (on ENST00000314830 / NM_170600.3; = p.L433V on NM_005489.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TARM1 | c.472G>A p.D158N (on ENST00000616041 / NM_001330650.1; = p.D150N on NM_001135686.3) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- UNK | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.334dup p.I112Nfs*29 | Frame Shift Ins (INS) | VAF 48/174 reads (28%) | called by mutect2, pindel, varscan2
- ZCCHC3 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF497 | c.821A>C p.H274P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZSCAN5C | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- BORA | c.1578G>A p.P526= (on ENST00000613797; = p.P451= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/277 reads (17%) | catalogued as rs554227453; called by muse, mutect2, varscan2
- C19orf54 | c.864G>C p.L288= | Silent (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2
- CTAGE15 | c.42G>C p.L14= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as rs747522011; called by muse, mutect2, varscan2
- FHOD3 | c.3441C>A p.I1147= (on ENST00000359247 / NM_001281739.3; = p.I1164= on NM_025135.5) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57165551; called by muse, mutect2
- FMR1NB | c.117G>A p.E39= | Silent (SNP) | VAF 53/85 reads (62%) | called by muse, mutect2, varscan2
- HUNK | c.879C>T p.A293= | Silent (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1152C>T p.D384= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as rs760074620; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCAPH | c.1803G>A p.Q601= | Silent (SNP) | VAF 51/269 reads (19%) | catalogued as rs377576873, COSV53635997; called by muse, mutect2, varscan2
- NPAS1 | c.1395G>T p.V465= | Silent (SNP) | VAF 44/286 reads (15%) | called by muse, mutect2, varscan2
- TENM2 | c.2502C>T p.G834= (on ENST00000518659 / NM_001122679.2; = p.G602= on NM_001080428.3) | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs374107882; called by muse, mutect2, varscan2
- TNS2 | c.2487C>A p.G829= (on ENST00000314250 / NM_170754.4; = p.G839= on NM_015319.2) | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- TOP1MT | c.141C>T p.H47= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs141679480; called by muse, mutect2, varscan2
- TRIM51GP | c.441A>G p.L147= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1162373902; called by muse, mutect2, varscan2
- WDR11 | c.3012A>G p.L1004= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as rs768066351; called by muse, mutect2, varscan2
- ZNF232 | c.801G>A p.Q267= | Silent (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- ZNF865 | c.3096C>G p.L1032= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- BNIP1 | c.490+787T>C | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- G6PC3 | c.-56T>A | 5'UTR (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2
- KATNBL1 | c.883-604T>C | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs1353240239; called by muse, mutect2
- STK32B | c.108+305C>G | Intron (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- UMPS | c.*4114A>G | 3'UTR (SNP) | VAF 6/104 reads (6%) | catalogued as rs1202621240; called by muse, mutect2
